Gene-level copy-number profile of tumor specimen ALCH-B2UZ-TTP1-A from ALCHEMIST case ALCH-B2UZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.4 years (26,813 days).
Specimen ALCH-B2UZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 021df25f-ce76-49da-a54d-8a0071b10d39.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2UZ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/5e10993d-ef7f-49eb-b4da-43c91da5466f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 3,176; copy number 2: 54,297; copy number 3: 807; copy number 4: 41; copy number 5: 1; copy number 7: 2; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,712,200–3,714,298, 1 gene (within-gene range 0–2): TP73-AS2.
- chr2:44,938,833–44,968,762, 5 genes (within-gene range 0–2): AC012354.3, AC012354.6, SIX3-AS1, SIX3, AC012354.1.
- chr2:232,406,844–232,525,716, 7 genes: ALPG, ECEL1P1, AC068134.2, DIS3L2P1, ALPI, ECEL1, PRSS56.
- chr2:239,068,817–239,085,926, 2 genes (within-gene range 0–2): MIR4440, MIR4441.
- chr12:132,489,551–132,585,188, 4 genes (within-gene range 0–2): FBRSL1, AC131212.3, AC131212.2, MIR6763.
- chr15:25,176,832–25,236,166, 33 genes (within-gene range 0–2): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36.
- chr16:1,206,560–1,207,124, 1 gene (within-gene range 0–2): AC120498.6.
- chr16:56,351,886–56,353,524, 1 gene (within-gene range 0–2): AC009102.2.
- chr16:86,520,383–86,523,897, 1 gene: AC009108.3.
- chr19:49,017,496–49,036,895, 7 genes (within-gene range 0–2): AC008687.4, CGB3, AC008687.1, NTF6A, NTF6G, CGB2, CGB1.
- chr22:18,623,339–18,653,617, 3 genes: SUSD2P2, CA15P2, PPP1R26P2.
- chr22:18,855,621–18,858,640, 1 gene (within-gene range 0–11): BCRP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:18,715,815–18,719,341, 1 gene, copy number 5: PPP1R26P4.
- chr22:18,773,665–18,843,399, 2 genes, copy number 7 (within-gene range 2–7): GGT3P, AC008132.2.
- chr22:18,846,811–18,861,049, 1 gene, copy number 11 (within-gene range 0–11): AC008132.1.

Autosomal genes at a single copy (total copy number 1): 832. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
